Somatic mutation profile of tumor specimen TCGA-DD-AAVV-01A (aliquot TCGA-DD-AAVV-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 56.8 years (20,751 days).
Specimen TCGA-DD-AAVV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90f96dfc-e602-494e-b977-f51963b2003c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVV-10A (Blood Derived Normal), aliquot TCGA-DD-AAVV-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c667b4cb-9baf-4e19-9390-a86b6ada7fec

The open-access MAF lists 130 somatic variants for this specimen: 101 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 25, Frame Shift Del 5, Nonsense Mutation 4, Intron 3, Translation Start Site 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXG1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as rs1057520663, CM152585, COSV100487063; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGAP3 | c.338C>T p.T113M (on ENST00000622464; = p.T149M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388061900, COSV100103928; called by muse, mutect2, varscan2
- BCL11A | c.1507G>A p.G503S (on ENST00000335712 / NM_001365609.1; = p.G537S on NM_018014.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as COSV100186463; called by muse, mutect2, varscan2
- BCL2L13 | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100456398; called by muse, mutect2
- CAMSAP2 | c.4301C>T p.T1434I (on ENST00000236925 / NM_001297707.2; = p.T1423I on NM_203459.3) | Missense Mutation (SNP) | VAF 68/417 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV99374275; called by muse, mutect2, varscan2
- CATSPERD | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as rs373865922; called by muse, mutect2
- CCDC63 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV99960874; called by muse, mutect2
- CFAP46 | c.6983T>C p.V2328A | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV99585513; called by muse, mutect2, varscan2
- CHRM3 | c.1123A>C p.S375R | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.173); catalogued as COSV99699431; called by muse, mutect2
- CNN3 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1311062311, COSV99598624; called by muse, mutect2, varscan2
- CNTLN | c.1190A>T p.N397I | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV99265589; called by muse, varscan2
- CNTN4 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1487597521, COSV101281557; called by muse, mutect2, varscan2
- COL4A4 | c.2609G>T p.G870V | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307672; called by muse, mutect2
- COL9A3 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as COSV100673578; called by muse, mutect2, varscan2
- DENND1A | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.996); catalogued as rs984089854; called by muse, mutect2
- DNAI3 | c.2041T>C p.S681P | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99642388; called by muse, mutect2
- DPY19L3 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639303; called by muse, mutect2, varscan2
- DSCAML1 | c.4291T>C p.F1431L (on ENST00000321322; = p.F1371L on NM_020693.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.992); catalogued as COSV100357179; called by muse, mutect2
- DYNC1LI1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 15/128 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV99818344; called by muse, mutect2, varscan2
- EHD3 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs1386920603, COSV100434873, COSV59029427; called by muse, mutect2, varscan2
- EIF3H | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.621); catalogued as COSV99412276; called by muse, mutect2, varscan2
- EPHA3 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100348489, COSV60728969; called by muse, mutect2, varscan2
- EPHA3 | c.2078A>G p.K693R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.987); catalogued as COSV100348493; called by muse, mutect2
- EPPK1 | c.5324A>G p.H1775R | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV73262459; called by muse, mutect2, varscan2
- EXOC7 | c.1484A>G p.K495R (on ENST00000335146 / NM_001145297.4; = p.K413R on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV100135747; called by muse, mutect2, varscan2
- F11 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.091); catalogued as rs748671250, COSV99251846; called by muse, mutect2
- FAT4 | c.2954A>C p.Y985S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV101272751; called by muse, mutect2
- FBN2 | c.7673G>A p.C2558Y | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99330525; called by muse, mutect2
- FNDC3A | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1317825970, COSV101001356; called by muse, mutect2
- FZR1 | c.836G>A p.W279* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100553845; called by muse, mutect2
- GAB2 | c.211G>A p.A71T (on ENST00000361507 / NM_080491.3; = p.A33T on NM_012296.3) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100416837; called by muse, mutect2, varscan2
- GABRG2 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729841; called by muse, mutect2, varscan2
- GFI1 | c.1064T>C p.M355T | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99647630; called by muse, mutect2
- GPR179 | c.2786T>A p.L929Q (on ENST00000621958; = p.L928Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1287520441; called by muse, mutect2, varscan2
- GREB1 | c.4964A>G p.D1655G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV99303768; called by muse, mutect2, varscan2
- GRIA1 | c.1964A>G p.K655R | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV99602242; called by muse, mutect2, varscan2
- HSD3B1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs587764853, COSV99348087; called by muse, mutect2, varscan2
- IDH1 | c.593A>C p.Q198P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV100577319; called by muse, mutect2, varscan2
- IGDCC4 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100733136; called by muse, mutect2, varscan2
- IGSF1 | c.73A>C p.M25L | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100812303; called by muse, mutect2
- IL4I1 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as COSV100352334; called by muse, mutect2, varscan2
- INPP5B | c.805G>A p.G269R (on ENST00000373023; = p.G189R on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV65961575; called by muse, mutect2
- KLHDC8A | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100903876; called by muse, mutect2, varscan2
- KLK6 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100037844, COSV59564993; called by muse, mutect2, varscan2
- LIPF | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99490619; called by muse, mutect2, varscan2
- LPIN1 | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.591); catalogued as COSV99878160; called by muse, mutect2, varscan2
- MAML3 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV100505477; called by muse, mutect2, varscan2
- MCTP1 | c.2394C>A p.C798* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100388134, COSV56522063; called by muse, mutect2, varscan2
- MCTP1 | c.2393G>A p.C798Y | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100388137; called by muse, mutect2, varscan2
- MED30 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.239); catalogued as COSV99816125; called by muse, mutect2
- MS4A10 | c.499A>C p.I167L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as COSV100382425; called by muse, mutect2, varscan2
- MS4A4A | c.374C>G p.T125S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as COSV100557921; called by muse, mutect2, varscan2
- MUC5B | c.7096C>A p.P2366T | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV101500744; called by muse, mutect2, varscan2
- MYH7B | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs371353626; called by muse, mutect2, varscan2
- NIPBL | c.1031T>C p.M344T | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV99242561; called by muse, mutect2, varscan2
- NRDC | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.544); catalogued as COSV100703841; called by muse, mutect2, varscan2
- OBSCN | c.4534T>C p.Y1512H | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99484046; called by muse, mutect2, varscan2
- OPLAH | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV101470932; called by muse, mutect2, varscan2
- OR1Q1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939353; called by muse, mutect2, varscan2
- OR2AG1 | c.10T>C p.W4R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1232523735, COSV100264979; called by muse, mutect2, varscan2
- OR2M3 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs1190528880, COSV71758925; called by muse, mutect2
- OR51L1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1370241599, COSV58625173; called by muse, mutect2
- OR5J2 | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV100399231, COSV56622158; called by muse, mutect2, varscan2
- OR8K3 | c.275T>G p.I92S | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV100449897; called by muse, mutect2
- PHACTR3 | c.1267C>G p.P423A | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100733175; called by muse, mutect2
- PLXNC1 | c.4492T>G p.S1498A | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV99313790; called by muse, mutect2
- POLK | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99606465; called by muse, mutect2, varscan2
- PRDM10 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100457023; called by muse, mutect2
- PREX2 | c.3143A>T p.D1048V | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.52); catalogued as COSV99909814; called by muse, mutect2, varscan2
- PRKG1 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100907494, COSV64770226; called by muse, mutect2, varscan2
- REEP4 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as COSV100098261; called by muse, mutect2, varscan2
- RGS18 | c.539T>A p.V180E | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100817900; called by muse, mutect2, varscan2
- RHOB | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV55356061, COSV99695361; called by muse, mutect2
- RLN1 | c.347T>A p.V116E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as COSV99802835; called by muse, mutect2, varscan2
- RPRD2 | c.2472T>G p.D824E | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100955354; called by muse, mutect2
- RYR1 | c.3661G>T p.G1221C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100616934; called by muse, mutect2, varscan2
- SH3PXD2B | c.1799A>C p.H600P | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100288465; called by muse, mutect2, varscan2
- SLC1A3 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468223; called by muse, mutect2, varscan2
- SPATA1 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 35/715 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); catalogued as COSV99759951; called by muse, mutect2
- STXBP4 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1480428015, COSV100178408; called by muse, mutect2, varscan2
- SVIP | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.242); catalogued as COSV100829818; called by muse, mutect2, varscan2
- TAF1L | c.3162A>T p.E1054D | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99645378; called by muse, mutect2, varscan2
- TAS2R7 | c.56T>A p.V19E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99553981; called by muse, mutect2, varscan2
- TASOR2 | c.5227del p.E1743Sfs*3 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV100051010; called by mutect2, pindel, varscan2
- THEM4 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs762362153; called by mutect2, varscan2
- TIPARP | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV99903992; called by muse, mutect2
- TNS1 | c.1090A>T p.S364C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV99411850; called by muse, mutect2, varscan2
- TOX2 | c.1441A>T p.R481W (on ENST00000358131 / NM_001098798.2; = p.R457W on NM_032883.3) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100364622; called by muse, mutect2, varscan2
- UGT2B11 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV101485296, COSV71422950; called by muse, mutect2
- WDR49 | c.1998G>T p.E666D (on ENST00000308378 / NM_001366158.1; = p.E1007D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99248398; called by muse, mutect2, varscan2
- WT1 | c.887+2T>C p.X296_splice | Splice Site (SNP) | VAF 13/158 reads (8%) | catalogued as CS984675, COSV60075347; called by muse, mutect2
- ZNF384 | c.660C>A p.D220E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.048); catalogued as COSV100158872; called by muse, mutect2, varscan2
- ZNF616 | c.1940A>G p.H647R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100348604; called by muse, mutect2
- FAU | c.256del p.V86* | Frame Shift Del (DEL) | VAF 13/115 reads (11%) | called by mutect2, pindel, varscan2
- IGF2 | c.577del p.R193Afs*22 (on ENST00000434045 / NM_001127598.3; = p.R137Afs*22 on NM_000612.6) | Frame Shift Del (DEL) | VAF 25/142 reads (18%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2
- IGLV5-37 | c.365C>G p.A122G | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC2 | c.4181A>T p.K1394M | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- PTPN3 | c.2160_2161del p.L721Afs*90 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- VIPAS39 | c.196del p.S66Vfs*23 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- ASPH | c.99G>A p.R33= | Silent (SNP) | VAF 4/79 reads (5%) | catalogued as COSV100727776; called by muse, mutect2
- BICRA | c.2250C>G p.P750= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV101194466; called by muse, mutect2, varscan2
- BMP15 | c.813T>C p.G271= | Silent (SNP) | VAF 68/137 reads (50%) | catalogued as COSV99399529; called by muse, mutect2, varscan2
- CPOX | c.336G>A p.S112= | Silent (SNP) | VAF 44/686 reads (6%) | catalogued as COSV99939184; called by muse, mutect2
- EGFLAM | c.2190C>T p.C730= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV100380287; called by muse, mutect2, varscan2
- ERMARD | c.327A>G p.E109= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV100824924; called by muse, mutect2, varscan2
- FASN | c.6666G>T p.L2222= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100148308; called by muse, mutect2
- FLT1 | c.342T>C p.T114= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99166551; called by muse, mutect2
- FNDC1 | c.1008T>C p.R336= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV51937049; called by muse, mutect2
- FSIP1 | c.1128C>G p.R376= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100618342, COSV63223904; called by muse, mutect2, varscan2
- GALNT5 | c.441A>G p.R147= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99375578; called by muse, mutect2, varscan2
- GLA | c.93A>T p.A31= | Silent (SNP) | VAF 11/216 reads (5%) | catalogued as COSV99516591; called by muse, mutect2
- HERC1 | c.6984T>C p.T2328= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV101496894; called by muse, mutect2
- KALRN | c.8868A>G p.A2956= (on ENST00000360013 / NM_001024660.4; = p.A1259= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as rs998847211, COSV99362913; called by muse, mutect2, varscan2
- LIN54 | c.1239A>G p.K413= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as COSV100464994; called by muse, mutect2
- MYH10 | c.5455C>T p.L1819= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99346315; called by muse, mutect2
- MYO18B | c.2769G>C p.V923= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV100125103; called by muse, mutect2, varscan2
- OR13C5 | c.759G>T p.G253= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV101053167, COSV66164628; called by muse, mutect2, varscan2
- OR4K1 | c.27G>A p.V9= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs1195199863, COSV99579366; called by muse, mutect2, varscan2
- PNO1 | c.243A>C p.P81= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV54561927; called by muse, mutect2, varscan2
- SH2D3A | c.780C>T p.A260= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs145201987; called by muse, mutect2, varscan2
- SLC44A4 | c.597C>T p.T199= | Silent (SNP) | VAF 5/103 reads (5%) | catalogued as COSV99999273; called by muse, mutect2
- SVIL | c.1134G>A p.K378= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100881533; called by muse, mutect2
- SYT2 | c.1035C>T p.I345= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100937198; called by muse, mutect2, varscan2
- TCF21 | c.117G>A p.E39= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV99399760; called by muse, mutect2, varscan2
- ALAS2 | c.-15-1787A>G | Intron (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100238633; called by muse, mutect2, varscan2
- COL11A1 | c.898-188A>T | Intron (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100617987; called by muse, mutect2, varscan2
- MFSD4B | c.*687A>G | 3'UTR (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100920614; called by muse, mutect2, varscan2
- PCDH11X | c.3033+3665G>A | Intron (SNP) | VAF 255/438 reads (58%) | catalogued as COSV100015066; called by muse, mutect2, varscan2
